Surgical pathology report (de-identified scan), TCGA case TCGA-05-4417, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4417-01A (Primary Tumor).

[REDACTED]

[REDACTED]/diagnoses:

Peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right upper lobe of the lung with a large-cell and clear-cell, solid and acinar component, slight mucin formation and main localization in S3.

TNM classification on the basis of this material pT2 pN0 pMX R0, stage IB.

[REDACTED]

Comment/supplementary remark:

The tumor has extended over the oblique fissure of the lung into adjoining segments of S4 and S5. The resection margin of the bronchus and vessels and all the lymph nodes removed are tumor-free.

Source: NCI Genomic Data Commons file 1eb9f67d-f6dc-46b9-bbae-cf7c82231424 (TCGA-05-4417.0B795830-D3BF-4A94-8355-B76A5F4469A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).